Somatic mutation profile of tumor specimen BA2081D (aliquot aq-BA2081D) from BEATAML1.0 case 2358, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.6 years (23,590 days).
Specimen BA2081D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91bbaed5-22b2-44b3-ac17-420fdea5d968.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2954D (Solid Tissue Normal), aliquot aq-BA2954D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88320e84-1e9f-45d8-9e26-5a5fc8f97dc5

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Ins 3, 5'Flank 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/408 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACAN | c.5647G>A p.D1883N | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs757229334, COSV61365046; called by muse, mutect2
- ITGB7 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57238998; called by muse, mutect2
- MTCL1 | c.2866C>T p.R956W (on ENST00000306329 / NM_001378206.1; = p.R596W on NM_015210.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1235737279; called by muse, mutect2, varscan2
- RBBP5 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV52706451; called by muse, mutect2
- SSUH2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs185229238; called by mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- DHX34 | c.1328C>G p.A443G | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FBXL17 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- ITPRIPL1 | c.398_399insGGAA p.H133Qfs*3 (on ENST00000439118 / NM_001008949.3; = p.H141Qfs*3 on NM_178495.6) | Frame Shift Ins (INS) | VAF 20/159 reads (13%) | called by mutect2, varscan2
- LNX1 | c.1895G>T p.C632F (on ENST00000263925 / NM_001126328.3; = p.C536F on NM_032622.2) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PHLDB3 | c.1225dup p.R409Pfs*9 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- GLG1 | c.48G>T p.A16= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1353658024; called by muse, mutect2
- NFIA | chr1:61081981 A>G | 5'Flank (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- SEC13 | c.855+17del | Intron (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
